Somatic mutation profile of tumor specimen TCGA-L5-A8NI-01A (aliquot TCGA-L5-A8NI-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NI, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 79.8 years (29,135 days).
Specimen TCGA-L5-A8NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 844d5233-8189-46cb-b80f-7605b57ccd5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NI-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NI-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60329148-8c24-4bdc-b2ea-7fdbf8ebab14

The open-access MAF lists 217 somatic variants for this specimen: 172 protein-altering or splice-affecting, 42 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 42, Frame Shift Del 11, Nonsense Mutation 5, In Frame Del 4, Splice Site 4, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAMP1 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as rs797044962, CM129412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 24/32 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.2354C>T p.T785M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs371756212; called by muse, mutect2, varscan2
- ACO2 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53439510; called by muse, mutect2, varscan2
- ADGRE1 | c.1252del p.W418Gfs*16 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs1568349819; called by mutect2, pindel, varscan2
- ADGRG1 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as COSV65635603; called by muse, mutect2, varscan2
- AKAP17A | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 83/116 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs750340934; called by muse, mutect2, varscan2
- ASTN1 | c.1345T>G p.F449V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV56087061; called by muse, mutect2, varscan2
- ATG9B | c.2204T>G p.V735G | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52490673; called by muse, mutect2, varscan2
- C16orf54 | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.633); catalogued as COSV61476691; called by muse, mutect2, varscan2
- CACNA1G | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100662750; called by muse, mutect2, varscan2
- CBL | c.2384A>T p.N795I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV99876086; called by muse, mutect2, varscan2
- CFHR4 | c.1689A>C p.Q563H (on ENST00000367416 / NM_001201551.2; = p.Q317H on NM_006684.5) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV52237674; called by muse, mutect2, varscan2
- CFP | c.941-2A>T p.X314_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as rs1382968657; called by muse, mutect2, varscan2
- COL6A1 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs564072783, COSV100719981; called by muse, mutect2, varscan2
- CSMD3 | c.5486C>A p.S1829Y (on ENST00000297405 / NM_001363185.1; = p.S1725Y on NM_052900.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52276676; called by muse, mutect2, varscan2
- CSMD3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV52116447; called by muse, mutect2, varscan2
- DRD1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as rs767462851; called by muse, mutect2, varscan2
- EPHA5 | c.2172A>C p.E724D | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV56642308; called by muse, mutect2, varscan2
- FAT1 | c.2758G>A p.V920I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV71674842; called by muse, mutect2, varscan2
- FBLN2 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs756161270, COSV55489238, COSV55492759; called by muse, mutect2, varscan2
- FCHSD1 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs746301997; called by muse, mutect2, varscan2
- FOXG1 | c.1384A>G p.S462G | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs752379833, COSV100486474, COSV104398698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYN | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1410454124; called by muse, mutect2, varscan2
- HAPLN4 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.5); catalogued as rs1470011571, COSV52269249; called by muse, mutect2, varscan2
- IRS1 | c.2042G>A p.S681N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV100524803; called by muse, mutect2, varscan2
- ITIH5 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs756685410, COSV53670259; called by muse, mutect2, varscan2
- KCNJ15 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as COSV60810408; called by muse, mutect2, varscan2
- KDM4D | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs371293647; called by muse, mutect2, varscan2
- LMO7 | c.4424G>A p.R1475H (on ENST00000357063; = p.R1156H on NM_005358.5) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs185108401; called by muse, mutect2, varscan2
- MAPK11 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); catalogued as rs200417198, COSV104399576, COSV57998444; called by muse, mutect2, varscan2
- MAPKAP1 | c.646A>G p.S216G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs781541256; called by muse, mutect2, varscan2
- MLXIPL | c.1080C>G p.N360K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs782298020; called by muse, mutect2, varscan2
- MMP16 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV54159400; called by muse, mutect2, varscan2
- MMS22L | c.1397G>C p.C466S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV51522202; called by muse, mutect2, varscan2
- MUC3A | c.9104C>T p.S3035L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs985748159; called by muse, varscan2
- OPN5 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV55248216; called by muse, mutect2, varscan2
- OR6S1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs147595648; called by muse, mutect2, varscan2
- OR8G5 | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100422303; called by muse, mutect2
- PAK6 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1378608525; called by muse, mutect2, varscan2
- PANK4 | c.1706G>C p.W569S | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs940808017; called by muse, mutect2, varscan2
- PCDHB3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1415382355; called by muse, mutect2, varscan2
- PPP2R5C | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV58269897; called by muse, mutect2, varscan2
- RASGRF2 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99428167; called by muse, mutect2, varscan2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SERTAD4 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs1480898565; called by muse, mutect2, varscan2
- SLC9A3R1 | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1307140220, COSV52852970; called by muse, mutect2, varscan2
- STIM2 | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.437); catalogued as COSV52840808; called by muse, mutect2, varscan2
- TRHDE | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs957181752; called by muse, mutect2, varscan2
- TTN | c.32361A>C p.K10787N (on ENST00000591111; = p.K9860N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | PolyPhen possibly damaging (0.787); catalogued as COSV60195369; called by muse, mutect2, varscan2
- WDR54 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV51762924; called by muse, mutect2, varscan2
- ABCC8 | c.464_474del p.V155Gfs*113 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADARB1 | c.682_696delinsC p.F228Rfs*18 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by pindel, varscan2*
- ADCY8 | c.2424T>G p.D808E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ADGRV1 | c.15316G>A p.D5106N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AFDN | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AGPS | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AKAP1 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.10223G>T p.G3408V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQR | c.1120T>G p.S374A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP28 | c.874T>C p.Y292H (on ENST00000383472 / NM_001366230.1; = p.Y133H on NM_001010000.3) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ARHGEF10L | c.1357_1388del p.G453Tfs*35 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- ARID1B | c.4206C>A p.D1402E | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARID3B | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARIH2 | c.161T>A p.F54Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.306); called by muse, varscan2
- ARRDC2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BSPRY | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- C1orf158 | c.5T>G p.F2C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CD248 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPF | c.4492_4507del p.A1498Qfs*7 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel
- CHD5 | c.2558A>G p.K853R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHD8 | c.7699C>G p.P2567A (on ENST00000646647 / NM_001170629.2; = p.P2288A on NM_020920.4) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CHRM3 | c.144T>A p.N48K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLDN17 | c.122T>G p.I41S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- CNKSR2 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COMMD2 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CPS1 | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRB2 | c.2199C>A p.F733L | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSN1S1 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.6590A>G p.E2197G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP4F22 | c.777_796del p.D260Gfs*3 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.431del p.L144Cfs*2 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- DCP1A | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2
- DCTN1 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DDX56 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH1 | c.7862G>T p.W2621L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH8 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMT3B | c.2345A>T p.K782I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DUS2 | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- EPS15L1 | c.2395G>A p.V799I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EPSTI1 | c.930G>A p.M310I (on ENST00000398762 / NM_001330543.2; = p.M299I on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ESCO1 | c.765_793del p.V256Gfs*8 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel
- FBXW7 | c.1919del p.S640Tfs*7 (on ENST00000281708 / NM_001349798.2; = p.S560Tfs*7 on NM_018315.5) | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- FLOT2 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT16 | c.1633G>C p.A545P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- GARNL3 | c.1356+1G>T p.X452_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- GOLGB1 | c.5490C>G p.S1830R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPATCH3 | c.78_80del p.A27del | In Frame Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel*, varscan2
- GPC6 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- GRM1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLX | c.1412C>G p.A471G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- HNRNPLL | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HOXB2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 44/169 reads (26%) | called by muse, mutect2, varscan2
- HRNR | c.1462T>G p.S488A | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- IGSF22 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISX | c.30C>G p.C10W | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KASH5 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- KCNH1 | c.1100A>G p.K367R (on ENST00000271751 / NM_172362.3; = p.K340R on NM_002238.4) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KCNK2 | c.95A>C p.K32T (on ENST00000444842 / NM_001017425.3; = p.K17T on NM_014217.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- KIF18A | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF27 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- KIFC2 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRRK2 | c.6934A>T p.R2312* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- MAGEA10 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MEA1 | c.406+2T>A p.X136_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- MLN | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MORC3 | c.1572_1574del p.L525del | In Frame Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- MROH2B | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSRA | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYH2 | c.1505A>G p.E502G | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MYO1D | c.516_530delinsGATATTGATA p.F172Lfs*10 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by pindel, varscan2*
- NLGN1 | c.959T>G p.V320G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR11L1 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- OR2A2 | c.499T>G p.F167V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR52J3 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OSBP | c.1705A>C p.T569P | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- OVCH2 | c.1068T>G p.S356R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAK5 | c.607T>G p.L203V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAMR1 | c.787T>G p.L263V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH1 | c.2908C>G p.R970G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PCDHAC1 | c.1505C>A p.S502* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- PCLO | c.14207T>G p.L4736R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.8404G>A p.A2802T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PDE1A | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PEAK1 | c.4231_4251del p.P1411_D1417del | In Frame Del (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- PITPNM2 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PITPNM3 | c.1439T>G p.L480R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PLBD2 | c.986A>C p.K329T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PLCH1 | c.3556T>G p.L1186V (on ENST00000340059 / NM_001130960.2; = p.L1178V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PLCZ1 | c.417T>A p.D139E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRG4 | c.2636A>G p.E879G | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PTGER4 | c.86T>G p.I29S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- RAP2A | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RFC1 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RUFY3 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- SEC16A | c.5083G>A p.D1695N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCD1 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SNX6 | c.307A>G p.I103V (on ENST00000652385; = p.I91V on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPAG17 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ST13 | c.981+1G>C p.X327_splice | Splice Site (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- SYT2 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TAAR2 | c.360_389del p.S121_S130del (on ENST00000367931 / NM_001033080.1; = p.S76_S85del on NM_014626.3) | In Frame Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- TAF10 | c.307del p.A103Pfs*5 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- TASOR | c.3783A>C p.L1261F (on ENST00000355628 / NM_001365636.2; = p.L885F on NM_015224.3) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D9 | c.502T>A p.Y168N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, varscan2
- TCAIM | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TG | c.4544A>T p.Q1515L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TNC | c.6476G>T p.G2159V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFAIP3 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFRSF19 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSEN34 | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TTC39B | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- UBQLNL | c.71A>T p.K24I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- UNC93B1 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2
- UTY | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- VPS51 | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WDHD1 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ZNF292 | c.3878A>G p.N1293S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF670 | c.1100G>C p.C367S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN20 | c.1850T>G p.L617W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- AHCYL2 | c.1509A>G p.Q503= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs764291375; called by muse, mutect2, varscan2
- AJAP1 | c.1071T>C p.S357= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV65449730; called by muse, mutect2, varscan2
- ATP6AP1 | c.312A>G p.A104= | Silent (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- BPIFB4 | c.378C>T p.A126= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs772687337, COSV64951085; called by muse, mutect2, varscan2
- BRCA1 | c.5298C>A p.I1766= | Silent (SNP) | VAF 36/50 reads (72%) | called by muse, mutect2, varscan2
- C7 | c.234A>C p.G78= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- CACNA1G | c.270C>T p.V90= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV61734461; called by muse, mutect2, varscan2
- CCDC83 | c.337T>C p.L113= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- DECR1 | c.792C>T p.G264= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- DST | c.12963A>G p.E4321= (on ENST00000361203 / NM_001374722.1; = p.E1909= on NM_015548.5) | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- FMNL1 | c.1671C>G p.A557= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- IL1RAPL1 | c.2061G>A p.R687= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- LRP3 | c.666G>A p.A222= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs749141618, COSV53504570; called by muse, varscan2
- METTL21A | c.78T>C p.F26= | Silent (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- NAT2 | c.603T>C p.D201= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs772309919; called by muse, mutect2, varscan2
- NOXO1 | c.705A>G p.L235= (on ENST00000397280 / NM_172168.3; = p.L229= on NM_144603.4) | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- NXF1 | c.1551C>T p.F517= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.1671C>T p.N557= | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- PPP1R14C | c.450G>A p.R150= | Silent (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- PSG2 | c.816T>A p.S272= | Silent (SNP) | VAF 72/180 reads (40%) | catalogued as COSV61544747; called by muse, mutect2, varscan2
- PTGER4 | c.87C>A p.I29= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- RP2 | c.660T>A p.I220= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- RUFY1 | c.468C>G p.L156= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- RUFY3 | c.1017G>C p.G339= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56913578; called by muse, mutect2, varscan2
- SEC16A | c.5781G>A p.G1927= | Silent (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2, varscan2
- SEMA4C | c.297T>C p.C99= | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- SLU7 | c.1095A>G p.K365= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- SMOC1 | c.703C>T p.L235= | Silent (SNP) | VAF 20/36 reads (56%) | called by muse, varscan2
- STX3 | c.13C>T p.L5= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1436293019; called by muse, mutect2, varscan2
- THSD7B | c.1227A>G p.K409= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV55690351, COSV55692227, COSV99753646; called by muse, mutect2, varscan2
- TMEM109 | c.309C>T p.A103= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1200232953, COSV99134756; called by muse, mutect2, varscan2
- TMEM202 | c.177C>G p.L59= | Silent (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.297A>G p.K99= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- TRMT9B | c.780T>C p.T260= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1246402007; called by muse, mutect2, varscan2
- TTLL5 | c.669C>T p.D223= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs543743763; called by muse, mutect2, varscan2
- TTN | c.53481G>A p.R17827= (on ENST00000591111; = p.R10403= on NM_003319.4) | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs1432510800, COSV60056873; called by muse, mutect2, varscan2
- TUBA3C | c.717G>A p.T239= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as rs397839852; called by muse, mutect2, varscan2
- USP53 | c.1500A>G p.K500= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- USP9Y | c.5433A>C p.A1811= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- UTP20 | c.7977G>C p.G2659= | Silent (SNP) | VAF 24/39 reads (62%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.741T>C p.D247= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- ZNF229 | c.1911C>T p.F637= | Silent (SNP) | VAF 105/162 reads (65%) | called by muse, mutect2, varscan2
- IL9R | c.-2T>G | 5'UTR (SNP) | VAF 62/151 reads (41%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.520+576C>T | Intron (SNP) | VAF 15/28 reads (54%) | catalogued as rs1203735315; called by muse, mutect2, varscan2
- SSPOP | n.10584G>A | RNA (SNP) | VAF 8/12 reads (67%) | catalogued as rs562328149; called by muse, mutect2, varscan2
